Somatic mutation profile of tumor specimen 11b5a745-03a6-4c05-9000-534bf3 (aliquot 11b5a745-03a6-4c05-9000-534bf3_D6) from CPTAC case 04OV023, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV.
Specimen 11b5a745-03a6-4c05-9000-534bf3: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72903783-54cf-4dc3-86cd-83392539f61b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 7671658a-0610-4167-b2ba-0ba841 (Blood Derived Normal), aliquot 7671658a-0610-4167-b2ba-0ba841_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/154d9724-5eb9-462a-a9fd-365b5f1e7304

The open-access MAF lists 100 somatic variants for this specimen: 66 protein-altering or splice-affecting, 18 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 18, Frame Shift Del 8, Intron 8, RNA 5, Nonsense Mutation 4, In Frame Del 2, 5'UTR 2, Splice Region 1, 5'Flank 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPM1D | c.1636dup p.L546Pfs*6 | Frame Shift Ins (INS) | VAF 153/277 reads (55%) | catalogued as rs1194694298; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- AHNAK2 | c.5341G>A p.D1781N | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.67); catalogued as rs756808914, COSV60912944; called by muse, mutect2
- FGF4 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51451169; called by muse, mutect2, varscan2
- FGFBP3 | c.729G>C p.E243D | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1009124043; called by muse, mutect2
- GABRB3 | c.174G>C p.E58D | Missense Mutation (SNP) | VAF 120/465 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV59482205; called by muse, mutect2
- GBP7 | c.387C>G p.N129K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54010373; called by muse, mutect2, varscan2
- HAGHL | c.797A>C p.E266A (on ENST00000341413; = p.*228Cext*15 on NM_001365282.1) | Missense Mutation (SNP) | VAF 106/319 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as COSV99284989; called by muse, mutect2, varscan2
- HCFC1 | c.4667C>G p.S1556C | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); catalogued as rs782115386; called by muse, mutect2, varscan2
- HERC2 | c.2237G>A p.R746H | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs766238180, COSV55314709, COSV55317576; called by muse, mutect2, varscan2
- IL4R | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 22/453 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.052); catalogued as COSV99405278; called by muse, mutect2
- MAP4 | c.781G>T p.A261S | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV64237413; called by muse, mutect2, varscan2
- NECTIN1 | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 132/422 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as rs755806347, COSV50598637, COSV50602350; called by muse, varscan2
- NPHS1 | c.3213del p.L1072Ffs*71 | Frame Shift Del (DEL) | VAF 91/424 reads (21%) | catalogued as rs1420623853; called by pindel, varscan2
- NTN5 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as rs752844872; called by muse, mutect2, varscan2
- OTOG | c.2311G>A p.A771T | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs796079809; called by muse, mutect2, varscan2
- P4HA2 | c.1268T>G p.V423G | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs200725924; called by muse, mutect2, varscan2
- PALD1 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1174205581, COSV54979601; called by muse, mutect2, varscan2
- PLEKHG3 | c.1522G>A p.V508M (on ENST00000394691; = p.V564M on NM_001308147.2) | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs775037199, COSV55982517; called by muse, mutect2, varscan2
- RNF4 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58642179; called by muse, mutect2, varscan2
- RPTN | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 127/493 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs1340496498; called by muse, mutect2, varscan2
- RYR1 | c.15100G>C p.E5034Q | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV62108609; called by muse, varscan2
- SELE | c.1030C>A p.P344T | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV60973804; called by muse, mutect2, varscan2
- SYNPR | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1047982225, COSV55723084; called by muse, mutect2, varscan2
- VPS13D | c.7289G>T p.R2430L | Missense Mutation (SNP) | VAF 90/256 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV50628407; called by mutect2, varscan2
- ABTB1 | c.54G>A p.V18= | Splice Region (SNP) | VAF 32/83 reads (39%) | called by muse, mutect2, varscan2
- ACSM4 | c.808_832del p.S270Pfs*29 | Frame Shift Del (DEL) | VAF 26/137 reads (19%) | called by mutect2, pindel, varscan2
- AEBP2 | c.175C>A p.L59M | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.795); called by muse, mutect2
- ARHGEF33 | c.2471T>A p.L824H | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARMC2 | c.1137G>T p.L379F | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ATP1A3 | c.50A>G p.K17R (on ENST00000545399 / NM_001256214.2; = p.K4R on NM_152296.5) | Missense Mutation (SNP) | VAF 112/439 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAMK4 | c.565T>C p.S189P | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- CEP120 | c.2848_2860del p.E950Lfs*2 | Frame Shift Del (DEL) | VAF 16/118 reads (14%) | called by pindel, varscan2*
- CLECL1 | c.311G>C p.R104T | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.484); called by muse, mutect2
- DNAH1 | c.12220C>T p.L4074F | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- EIF3J | c.689G>C p.G230A | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXO42 | c.1511G>A p.W504* | Nonsense Mutation (SNP) | VAF 119/324 reads (37%) | called by muse, mutect2, varscan2
- FHDC1 | c.749A>T p.N250I | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GALNT5 | c.2696T>A p.V899D | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- HEY1 | c.690_712del p.A231Tfs*57 | Frame Shift Del (DEL) | VAF 92/319 reads (29%) | called by mutect2, pindel, varscan2
- ISLR | c.170_188del p.L57Qfs*35 | Frame Shift Del (DEL) | VAF 91/286 reads (32%) | called by mutect2, pindel, varscan2
- LGI2 | c.274C>G p.L92V | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- LSMEM2 | c.140_166del p.Q47_S56delinsR | In Frame Del (DEL) | VAF 24/300 reads (8%) | called by mutect2, pindel
- MBD6 | c.2503del p.A835Pfs*111 | Frame Shift Del (DEL) | VAF 25/125 reads (20%) | called by mutect2, pindel, varscan2
- MCF2L2 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 33/91 reads (36%) | called by muse, mutect2, varscan2
- MYBPC1 | c.948G>T p.M316I (on ENST00000550270 / NM_206820.2; = p.M341I on NM_002465.4) | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2
- NBEAL1 | c.5870_5897del p.H1957Lfs*38 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel
- NIPA2 | c.485C>A p.A162D | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- NOS3 | c.1444G>T p.G482W | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); called by muse, mutect2
- OR10W1 | c.887_906del p.L296Pfs*34 | Frame Shift Del (DEL) | VAF 27/85 reads (32%) | called by mutect2, pindel, varscan2
- OTOG | c.2312C>A p.A771D | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- PDCD11 | c.2900C>G p.S967* | Nonsense Mutation (SNP) | VAF 82/327 reads (25%) | called by muse, mutect2, varscan2
- PTDSS1 | c.831G>A p.W277* | Nonsense Mutation (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- RNF213 | c.6975C>A p.N2325K | Missense Mutation (SNP) | VAF 157/431 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- SIPA1L3 | c.2251G>A p.V751I | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- SYNRG | c.3878G>A p.C1293Y | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- THSD1 | c.1193C>G p.S398C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- TMUB2 | c.78_89del p.T27_E30del (on ENST00000538716 / NM_001353177.2; = p.T7_E10del on NM_024107.3 and 5 other RefSeq transcripts) | In Frame Del (DEL) | VAF 10/114 reads (9%) | called by mutect2, pindel
- TRAT1 | c.479G>T p.S160I | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TTC9 | c.252G>C p.L84F | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ULK2 | c.1605C>G p.I535M | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- USP36 | c.586+1_586+23del p.X196_splice | Splice Site (DEL) | VAF 44/135 reads (33%) | called by mutect2, pindel, varscan2
- WDR49 | c.48C>A p.F16L (on ENST00000308378 / NM_001366158.1; = p.F357L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ZIK1 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 10/300 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.114); called by muse, mutect2
- ZNF439 | c.1232A>C p.E411A | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- ZNF717 | c.2708G>T p.G903V | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF780A | c.839A>T p.K280M | Missense Mutation (SNP) | VAF 22/327 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- AMPH | c.663G>T p.A221= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV100343123; called by muse, mutect2, varscan2
- AP4M1 | c.750C>T p.V250= | Silent (SNP) | VAF 239/747 reads (32%) | catalogued as rs752745814; called by muse, varscan2
- DDAH1 | c.171G>A p.K57= | Silent (SNP) | VAF 28/84 reads (33%) | called by muse, mutect2, varscan2
- EIF2AK3 | c.2850G>C p.V950= | Silent (SNP) | VAF 60/241 reads (25%) | catalogued as rs780621963; called by muse, mutect2, varscan2
- EMILIN3 | c.732A>T p.L244= | Silent (SNP) | VAF 126/424 reads (30%) | called by muse, mutect2, varscan2
- FBXO47 | c.1299T>A p.A433= | Silent (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- GPX7 | c.57G>A p.A19= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- HEY2 | c.867T>A p.L289= | Silent (SNP) | VAF 87/200 reads (44%) | called by muse, mutect2, varscan2
- IGF1R | c.3714T>A p.P1238= | Silent (SNP) | VAF 152/613 reads (25%) | called by muse, mutect2, varscan2
- KCND3 | c.153C>T p.F51= | Silent (SNP) | VAF 121/395 reads (31%) | called by muse, mutect2, varscan2
- KIAA1109 | c.6240T>C p.H2080= | Silent (SNP) | VAF 38/152 reads (25%) | called by muse, mutect2, varscan2
- MAG | c.114C>T p.V38= | Silent (SNP) | VAF 17/246 reads (7%) | catalogued as rs1366418975; called by muse, mutect2
- MAML2 | c.2703A>C p.A901= | Silent (SNP) | VAF 18/656 reads (3%) | called by muse, mutect2
- NPAS3 | c.2601G>A p.T867= (on ENST00000356141 / NM_001164749.2; = p.T835= on NM_022123.3) | Silent (SNP) | VAF 202/666 reads (30%) | catalogued as rs1200113406; called by mutect2, varscan2
- NTSR2 | c.63C>T p.A21= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- OR5K2 | c.105T>C p.Y35= | Silent (SNP) | VAF 84/284 reads (30%) | called by muse, mutect2, varscan2
- SLC4A3 | c.1485A>T p.G495= | Silent (SNP) | VAF 82/295 reads (28%) | called by muse, mutect2, varscan2
- TJP3 | c.1578C>T p.R526= | Silent (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2
- ANKRD20A8P | n.1338C>A | RNA (SNP) | VAF 76/304 reads (25%) | called by muse, mutect2, varscan2
- BEND2 | c.-31G>A | 5'UTR (SNP) | VAF 70/165 reads (42%) | catalogued as rs1430509988; called by muse, mutect2, varscan2
- COL28A1 | c.1998+925C>T | Intron (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- CYP21A1P | n.1496C>T | RNA (SNP) | VAF 182/442 reads (41%) | called by muse, varscan2
- CYP4F24P | n.358T>A | RNA (SNP) | VAF 41/149 reads (28%) | catalogued as rs749713357; called by muse, mutect2, varscan2
- HMCN2 | c.14138-49G>A | Intron (SNP) | VAF 62/200 reads (31%) | called by muse, mutect2, varscan2
- HNF4A | c.115+1103C>G | Intron (SNP) | VAF 33/183 reads (18%) | called by muse, mutect2, varscan2
- LINC02090 | n.126G>C | RNA (SNP) | VAF 45/110 reads (41%) | called by muse, mutect2, varscan2
- MGAT4C | c.-112del | 5'UTR (DEL) | VAF 33/86 reads (38%) | called by mutect2, pindel, varscan2
- MTMR9 | c.1487-1229G>A | Intron (SNP) | VAF 32/116 reads (28%) | catalogued as rs1466113828; called by muse, mutect2, varscan2
- PKM | c.379-12T>C | Intron (SNP) | VAF 59/367 reads (16%) | called by muse, mutect2, varscan2
- RNF151 | c.246+139G>A | Intron (SNP) | VAF 50/226 reads (22%) | called by muse, mutect2, varscan2
- SHOX2 | c.346+557G>T | Intron (SNP) | VAF 41/157 reads (26%) | called by muse, varscan2
- SPCS2P4 | n.337G>C | RNA (SNP) | VAF 124/319 reads (39%) | called by muse, mutect2, varscan2
- TTBK1 | c.1986+6481_1986+6496del | Intron (DEL) | VAF 81/222 reads (36%) | called by mutect2, pindel, varscan2
- UBN1 | chr16:4847292 del CGGGCCGC | 5'Flank (DEL) | VAF 29/76 reads (38%) | called by mutect2, pindel, varscan2
